Somatic mutation profile of tumor specimen TCGA-4X-A9F9-01A (aliquot TCGA-4X-A9F9-01A-11D-A423-09) from TCGA case TCGA-4X-A9F9, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 58.0 years (21,168 days).
Specimen TCGA-4X-A9F9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e7d5db8-b77a-45ec-ad97-7b7d3328741e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4X-A9F9-10A (Blood Derived Normal), aliquot TCGA-4X-A9F9-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74f96e4c-4930-4519-9261-a1d8ec3340db

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOVA1 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57487587; called by muse, mutect2
- CYP4Z1 | c.1468G>T p.V490F | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2
- MYO1G | c.2695C>T p.L899= | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- SH2B1 | c.810G>T p.R270= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- STARD6 | c.414T>A p.P138= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
